Somatic mutation profile of tumor specimen TCGA-EE-A29L-06A (aliquot TCGA-EE-A29L-06A-12D-A196-08) from TCGA case TCGA-EE-A29L, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 79.0 years (28,870 days).
Specimen TCGA-EE-A29L-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ce18779-154d-4a95-bef8-e9b56643b2f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29L-10A (Blood Derived Normal), aliquot TCGA-EE-A29L-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3daef7ed-67ea-46a7-b036-4f04603dba9f

The open-access MAF lists 2,351 somatic variants for this specimen: 1,511 protein-altering or splice-affecting, 784 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,388, Silent 784, Nonsense Mutation 73, Intron 28, Splice Region 24, Splice Site 17, RNA 16, 5'UTR 5, In Frame Del 4, Frame Shift Del 4, 3'Flank 4, 3'UTR 3.

Variants (750 of 2,351; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs767586362, COSV56753117; ClinVar: pathogenic; called by mutect2, varscan2
- CNGB3 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 66/252 reads (26%) | catalogued as rs1554618417, COSV100181145, COSV60697847; ClinVar: pathogenic; called by mutect2, varscan2
- FBN1 | c.1843_1845del p.N615del | In Frame Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs1555399837; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KIAA1109 | c.2902C>T p.R968C | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1051597475, COSV52690863; ClinVar: pathogenic; called by mutect2, varscan2
- MARCHF10 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 39/207 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs17853369, COSV60886636; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 222/328 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAK5 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 46/131 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769939031, COSV62021293; called by mutect2, varscan2
- PCSK5 | c.2771G>A p.W924* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | hotspot (GDC flag); catalogued as COSV70451329; called by muse, mutect2, varscan2
- S100A3 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 42/125 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs571596892, COSV62876526, COSV62876899; called by muse, mutect2, varscan2
- TP53 | c.529_546del p.P177_C182del | In Frame Del (DEL) | VAF 19/27 reads (70%) | hotspot (GDC flag); called by mutect2, varscan2
- A2ML1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.443); catalogued as COSV55298165; called by muse, mutect2, varscan2
- AAAS | c.687C>T p.T229= | Splice Region (SNP) | VAF 52/179 reads (29%) | catalogued as rs781457941, COSV52934146; called by muse, mutect2, varscan2
- AADACL4 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV66107157; called by muse, mutect2, varscan2
- AARS2 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.443); catalogued as COSV55117411; called by muse, mutect2, varscan2
- ABCA1 | c.4639C>T p.P1547S | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1253880083, COSV66068516, COSV66070239; called by muse, mutect2, varscan2
- ABCA13 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs775184311, COSV70043314; called by mutect2, varscan2
- ABCA13 | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV70026288, COSV70048767; called by muse, mutect2, varscan2
- ABCA4 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 80/154 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs62645942, CM043238; ClinVar: uncertain significance / not provided; called by mutect2, varscan2
- ABCA8 | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV52211416; called by muse, mutect2
- ABCB4 | c.3536G>A p.G1179E (on ENST00000265723 / NM_018849.3; = p.G1172E on NM_000443.4) | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55941296; called by muse, mutect2, varscan2
- ABCC2 | c.1281T>G p.D427E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64988470; called by muse, mutect2, varscan2
- ABCC4 | c.3887A>G p.N1296S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs780390465, COSV65318014; called by muse, varscan2
- ABCC4 | c.3877T>C p.F1293L | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV65318019; called by muse, varscan2
- ABCC8 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 166/382 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV56857353; called by muse, mutect2, varscan2
- ABCG1 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.833); catalogued as COSV59210018; called by muse, mutect2, varscan2
- ABCG2 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV52949281; called by muse, mutect2, varscan2
- ABHD13 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65535446; called by muse, mutect2, varscan2
- ABRA | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 166/226 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as COSV61733530; called by muse, mutect2, varscan2
- AC006059.2 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as COSV59606546; called by muse, varscan2
- AC011448.1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52280136; called by muse, mutect2, varscan2
- AC098582.1 | c.3100G>A p.D1034N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs909573701, COSV52024367; called by mutect2, varscan2
- ACACB | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100623268; called by muse, mutect2, varscan2
- ACACB | c.6242C>T p.T2081I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58151546; called by mutect2, varscan2
- ACAN | c.5030A>G p.E1677G | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV61368695; called by muse, mutect2, varscan2
- ACAN | c.6212G>A p.G2071E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs1377902642, COSV61368703; called by muse, mutect2, varscan2
- ACBD3 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV64729752; called by mutect2, varscan2
- ACE | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV52007047; called by muse, mutect2, varscan2
- ACER1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as rs267605729, COSV56836877; called by muse, mutect2, varscan2
- ACMSD | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV51606719, COSV51609500; called by muse, mutect2, varscan2
- ACSM2B | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV61656653; called by muse, mutect2, varscan2
- ACSM4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs368493928; called by mutect2, varscan2
- ACSM5 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as COSV59374645; called by muse, mutect2, varscan2
- ACSS3 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV54100582; called by muse, mutect2, varscan2
- ACSS3 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV54100594; called by mutect2, varscan2
- ACSS3 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 90/147 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs762107489, COSV54100607; called by muse, mutect2, varscan2
- ACTC1 | c.838A>C p.T280P | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV51761316; called by muse, mutect2, varscan2
- ACVR2A | c.221T>G p.V74G | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV54028687; called by muse, mutect2, varscan2
- ADAM19 | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1291973076, COSV57438668, COSV99067876; called by muse, mutect2, varscan2
- ADAM9 | c.1398C>T p.F466= | Splice Region (SNP) | VAF 15/36 reads (42%) | catalogued as COSV65962295; called by muse, varscan2
- ADAMTS13 | c.3307C>T p.Q1103* | Nonsense Mutation (SNP) | VAF 44/212 reads (21%) | catalogued as COSV52471521; called by muse, mutect2, varscan2
- ADAMTS18 | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs766827255, COSV51420101; called by muse, mutect2, varscan2
- ADAMTS19 | c.3002G>A p.G1001E | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50783444; called by muse, mutect2, varscan2
- ADAMTS20 | c.2796G>A p.M932I | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV67138640; called by mutect2, varscan2
- ADAMTS20 | c.1800G>A p.M600I | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs535948704, COSV67131882; called by mutect2, varscan2
- ADAMTS4 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs779357556, COSV63491121; called by mutect2, varscan2
- ADAMTS8 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57297415, COSV57298308; called by muse, mutect2, varscan2
- ADAMTS9 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 125/616 reads (20%) | catalogued as rs774572932, COSV55789887; called by muse, mutect2, varscan2
- ADAMTSL1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52824876; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1869A>C p.E623D | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.45); PolyPhen benign (0.138); catalogued as COSV54467942; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750649271, COSV54467957; called by mutect2, varscan2
- ADARB2 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101187269; called by muse, mutect2, varscan2
- ADAT1 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57188369; called by muse, mutect2, varscan2
- ADCY10 | c.4744G>A p.E1582K | Missense Mutation (SNP) | VAF 75/125 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63238889; called by muse, mutect2, varscan2
- ADCY9 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53581471; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.51+1G>A p.X17_splice | Splice Site (SNP) | VAF 11/98 reads (11%) | catalogued as COSV58446512; called by mutect2, varscan2
- ADGRB1 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV60103195; called by muse, mutect2, varscan2
- ADGRD1 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as COSV55456453; called by muse, mutect2, varscan2
- ADGRE2 | c.2012G>A p.G671E | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59696166; called by muse, mutect2, varscan2
- ADGRG7 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56301012; called by muse, varscan2
- ADGRG7 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs144717099, COSV99841095; called by mutect2, varscan2
- ADGRL3 | c.2659T>A p.S887T (on ENST00000506720 / NM_001322402.2; = p.S819T on NM_015236.6) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV72231860; called by mutect2, varscan2
- ADGRL4 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV66065603; called by mutect2, varscan2
- ADHFE1 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs866386246, COSV52555413, COSV52555513; called by muse, mutect2, varscan2
- ADSS1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.35); catalogued as COSV58274953; called by muse, mutect2, varscan2
- AFDN | c.4339C>T p.Q1447* | Nonsense Mutation (SNP) | VAF 38/81 reads (47%) | catalogued as COSV60043708, COSV60056148; called by mutect2, varscan2
- AFF2 | c.2200C>G p.P734A | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV54006432; called by muse, mutect2, varscan2
- AFP | c.194A>T p.K65I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV56926979; called by muse, mutect2, varscan2
- AGAP1 | c.1984C>T p.R662* (on ENST00000304032 / NM_001037131.3; = p.R609* on NM_014914.5) | Nonsense Mutation (SNP) | VAF 30/112 reads (27%) | catalogued as COSV58321552; called by muse, mutect2, varscan2
- AGBL1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs371923647, COSV66871729; called by muse, mutect2, varscan2
- AGO1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV64596451; called by muse, varscan2
- AGO3 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 106/183 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV55796927; called by mutect2, varscan2
- AHNAK2 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 212/290 reads (73%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as rs1423671369, COSV60913661; called by muse, mutect2, varscan2
- ALK | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV66588305; called by muse, varscan2
- ALOX5 | c.739C>G p.R247G | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV65554290; called by muse, mutect2, varscan2
- ALPK1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749235785, COSV51587806; called by mutect2, varscan2
- ALS2CL | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV59673070; called by muse, mutect2
- AMBN | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV59828047; called by muse, mutect2, varscan2
- AMOT | c.2638C>T p.P880S (on ENST00000371959 / NM_001113490.1; = p.P471S on NM_133265.3) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as COSV59067865; called by muse, mutect2, varscan2
- AMY2A | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 130/210 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as rs1452542535, COSV101340672; called by mutect2, varscan2
- AMY2A | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1461085460; called by mutect2, varscan2
- ANGPTL4 | c.509A>T p.Q170L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV56845596; called by muse, varscan2
- ANK3 | c.9430C>T p.P3144S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.996); catalogued as COSV55079882; called by muse, varscan2
- ANK3 | c.2158G>A p.G720R | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55049945, COSV55059242; called by muse, mutect2, varscan2
- ANKAR | c.2525A>G p.N842S | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV55617803; called by muse, mutect2, varscan2
- ANKK1 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs768579058, COSV58274158; called by mutect2, varscan2
- ANKRD12 | c.1859C>T p.S620L | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV50846523; called by mutect2, varscan2
- ANKRD34A | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV60162020; called by muse, mutect2
- ANKRD34A | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60162012; called by muse, mutect2, varscan2
- ANKRD45 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as COSV60962489; called by muse, mutect2, varscan2
- ANKS6 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs760387934, COSV62052084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO4 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54585481; called by muse, mutect2, varscan2
- ANO5 | c.1202G>A p.W401* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV61090024; called by muse, mutect2, varscan2
- AP3D1 | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs756034211, COSV61427093; called by mutect2, varscan2
- APBA1 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs140108483; called by mutect2, varscan2
- APOB | c.9460G>A p.E3154K | Missense Mutation (SNP) | VAF 102/480 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51934657; called by muse, mutect2, varscan2
- APOB | c.5833G>A p.D1945N | Missense Mutation (SNP) | VAF 137/534 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51929211; called by muse, mutect2, varscan2
- APOB | c.5660C>T p.S1887L | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51951167; called by muse, mutect2, varscan2
- APOB | c.2126G>A p.G709E | Missense Mutation (SNP) | VAF 144/597 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51932296; called by muse, mutect2, varscan2
- APOBEC3D | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.069); catalogued as rs757469920, COSV53328595; called by muse, mutect2, varscan2
- APOBEC3G | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68470850; called by muse, mutect2
- APOL5 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as COSV50768396; called by muse, mutect2, varscan2
- APOL5 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 95/484 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.165); catalogued as COSV99968462; called by muse, mutect2, varscan2
- APOL5 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 92/477 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs759163236, COSV99968463; called by muse, varscan2
- ARAP1 | c.3713C>T p.A1238V (on ENST00000393609 / NM_001040118.2; = p.A993V on NM_015242.4) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs547455432, COSV61994767; called by mutect2, varscan2
- ARAP2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs767613247, COSV58291736; called by mutect2, varscan2
- ARFGEF2 | c.2570A>T p.N857I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV64214937; called by muse, mutect2, varscan2
- ARGFX | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV57683684; called by muse, mutect2, varscan2
- ARHGAP15 | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs147613962; called by muse, mutect2, varscan2
- ARHGAP17 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV51511928; called by mutect2, varscan2
- ARHGAP19 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.791); catalogued as COSV57395913; called by muse, mutect2, varscan2
- ARHGAP29 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs777187517, COSV53112147; called by mutect2, varscan2
- ARHGAP30 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV63519180; called by muse, mutect2, varscan2
- ARHGAP32 | c.4742G>A p.R1581Q (on ENST00000310343 / NM_001378025.1; = p.R1232Q on NM_014715.4) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs765797475, COSV100089551, COSV59855102; called by muse, mutect2, varscan2
- ARHGAP36 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 64/67 reads (96%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.987); catalogued as COSV52271576; called by muse, mutect2, varscan2
- ARHGEF11 | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV59358355; called by muse, mutect2, varscan2
- ARHGEF12 | c.3051A>C p.K1017N | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV63107193; called by muse, mutect2, varscan2
- ARHGEF37 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV61369809; called by muse, mutect2, varscan2
- ARHGEF40 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV53884018; called by muse, mutect2
- ARID1B | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51679487; called by muse, mutect2, varscan2
- ARID1B | c.2853C>A p.F951L | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as COSV51679502; called by mutect2, varscan2
- ARMC4 | c.2636T>A p.F879Y | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV59473097; called by mutect2, varscan2
- ARNTL | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100724874; called by muse, mutect2, varscan2
- ARNTL | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724875; called by muse, mutect2, varscan2
- ARPP21 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); catalogued as COSV51792572; called by muse, mutect2, varscan2
- ARSL | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 43/47 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0.377); catalogued as COSV66965893; called by muse, mutect2, varscan2
- ASAH2 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61484364; called by muse, mutect2, varscan2
- ASB10 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs755804051, COSV52000326; called by muse, mutect2, varscan2
- ASB15 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as COSV51928967; called by muse, mutect2, varscan2
- ASB6 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | catalogued as COSV52965873; called by muse, mutect2, varscan2
- ASH1L | c.5005A>T p.K1669* | Nonsense Mutation (SNP) | VAF 17/115 reads (15%) | catalogued as COSV100853588; called by mutect2, varscan2
- ASIC4 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV61733355; called by muse, mutect2, varscan2
- ASPM | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV54138106, COSV99659587; called by muse, mutect2, varscan2
- ASTL | c.1270C>T p.H424Y | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV60905337; called by mutect2, varscan2
- ASTN1 | c.2587G>A p.G863S | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1368166205, COSV56083624; called by muse, mutect2, varscan2
- ASZ1 | c.336A>T p.Q112H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV52916248; called by mutect2, varscan2
- ATCAY | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749534755, COSV56659030; called by muse, mutect2, varscan2
- ATG4B | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV59871342; called by muse, mutect2, varscan2
- ATG7 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV61610841; called by muse, mutect2, varscan2
- ATM | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV53772623; called by muse, mutect2, varscan2
- ATP13A5 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.02); catalogued as COSV60875018; called by muse, mutect2, varscan2
- ATP2A3 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59235036; called by muse, mutect2, varscan2
- ATP4A | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); catalogued as rs140861099; called by mutect2, varscan2
- ATP5PB | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV71953319; called by muse, mutect2, varscan2
- ATP6V0D2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53417644; called by mutect2, varscan2
- ATP6V1C2 | c.1157G>C p.R386P (on ENST00000272238 / NM_001039362.2; = p.R340P on NM_144583.4) | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.29); catalogued as COSV55353294; called by muse, mutect2, varscan2
- ATP7B | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1292467421, COSV54443752; called by muse, mutect2, varscan2
- ATP8B4 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs940798819, COSV52710402; called by mutect2, varscan2
- ATXN7 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV99895256; called by muse, mutect2, varscan2
- AXDND1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs868380930, COSV62648005; called by muse, mutect2, varscan2
- AXIN1 | c.1732T>C p.Y578H | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51992958; called by muse, mutect2, varscan2
- BAAT | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52290893; called by muse, mutect2, varscan2
- BACH2 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.163); catalogued as rs144153232; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1119-2A>T p.X373_splice | Splice Site (SNP) | VAF 44/127 reads (35%) | catalogued as COSV57637116; called by muse, mutect2, varscan2
- BANK1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV59849379; called by muse, mutect2, varscan2
- BARX2 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV55652339; called by muse, varscan2
- BAX | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.85); catalogued as rs1179344139, COSV53172275; called by muse, mutect2, varscan2
- BAX | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99509239; called by muse, mutect2, varscan2
- BBS4 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV51440089; called by muse, mutect2, varscan2
- BCAS3 | c.2386C>T p.R796C (on ENST00000390652 / NM_001353144.2; = p.R781C on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs773996890, COSV66771266; called by muse, mutect2, varscan2
- BCL11A | c.920G>A p.R307K (on ENST00000335712 / NM_001365609.1; = p.R341K on NM_018014.4) | Missense Mutation (SNP) | VAF 151/622 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV59636555; called by muse, mutect2, varscan2
- BCL7A | c.562-2A>G p.X188_splice (on ENST00000261822 / NM_001024808.3; = p.X209_splice on NM_020993.5) | Splice Site (SNP) | VAF 35/73 reads (48%) | catalogued as COSV55851010; called by muse, mutect2, varscan2
- BCLAF1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV62140394; called by muse, mutect2, varscan2
- BCOR | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs1443453511, COSV60709422, COSV60717662; called by mutect2, varscan2
- BEST2 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50377437; called by muse, mutect2, varscan2
- BEST3 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56995961; called by muse, mutect2, varscan2
- BHLHE40 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99848278; called by mutect2, varscan2
- BHLHE40 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99848280; called by muse, mutect2, varscan2
- BMP10 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs779454423, COSV54894444, COSV99770624; called by muse, mutect2, varscan2
- BOD1L1 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV50049529; called by muse, mutect2, varscan2
- BPIFA1 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV62825166; called by muse, mutect2, varscan2
- BPIFB3 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV64958151; called by muse, varscan2
- BPTF | c.5692C>T p.Q1898* | Nonsense Mutation (SNP) | VAF 48/205 reads (23%) | catalogued as COSV58846148; called by mutect2, varscan2
- BRD4 | c.3445C>T p.R1149W | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs779348570, COSV54590688; called by mutect2, varscan2
- BRDT | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV100746342, COSV62867386; called by muse, mutect2, varscan2
- BRINP1 | c.1824G>A p.W608* | Nonsense Mutation (SNP) | VAF 41/156 reads (26%) | catalogued as COSV56297934; called by muse, mutect2, varscan2
- BRINP1 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.159); catalogued as rs372190683; called by muse, mutect2, varscan2
- BRINP2 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64177196; called by muse, mutect2, varscan2
- BRINP3 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750809290, COSV66521343, COSV66523532; called by muse, mutect2, varscan2
- BRMS1L | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV53764431; called by muse, mutect2, varscan2
- BRSK1 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100474566, COSV58669820; called by mutect2, varscan2
- BRWD1 | c.4937T>C p.V1646A | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV60902412; called by muse, mutect2, varscan2
- BSND | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV64871347; called by muse, mutect2, varscan2
- BTBD1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV55604656; called by mutect2, varscan2
- BTBD11 | c.1925C>T p.P642L (on ENST00000280758 / NM_001018072.2; = p.P179L on NM_001017523.2) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763745879, COSV55036568; called by muse, mutect2, varscan2
- BTN3A3 | c.292T>G p.S98A | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV99765033; called by muse, mutect2, varscan2
- BTN3A3 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs138755245; called by mutect2, varscan2
- BUD13 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 213/498 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52770418; called by muse, mutect2, varscan2
- C12orf66 | c.278T>A p.I93N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV61324665; called by muse, mutect2, varscan2
- C14orf39 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 72/304 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100408223, COSV58780369; called by muse, mutect2, varscan2
- C16orf89 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1404900255, COSV60126426; called by muse, mutect2, varscan2
- C1QTNF1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1481466822, COSV59264197; called by muse, mutect2, varscan2
- C1orf94 | c.781G>A p.D261N (on ENST00000488417 / NM_001134734.2; = p.D71N on NM_032884.5) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV64915657; called by muse, mutect2, varscan2
- C3orf62 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775550982, COSV55540349; called by muse, mutect2, varscan2
- C3orf84 | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV60412680; called by muse, mutect2, varscan2
- C5orf51 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV67566406; called by muse, mutect2
- C8A | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs1043425650, COSV63483624; called by muse, varscan2
- C8B | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs773136580, COSV100980903; called by mutect2, varscan2
- CA3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV53409684; called by muse, mutect2, varscan2
- CA8 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs868772164, COSV58774433; called by muse, mutect2, varscan2
- CABP2 | c.492C>T p.F164= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV53709686; called by mutect2, varscan2
- CACNA1B | c.3628C>T p.H1210Y | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53147304; called by mutect2, varscan2
- CACNA1C | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV59767233; called by muse, varscan2
- CACNA1E | c.3224C>T p.P1075L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV62382207; called by muse, mutect2, varscan2
- CACNA1E | c.6461G>A p.R2154K (on ENST00000367573 / NM_001205293.3; = p.R2111K on NM_000721.4) | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV62403035, COSV62414632; called by muse, mutect2, varscan2
- CACNA1E | c.6688G>A p.E2230K (on ENST00000367573 / NM_001205293.3; = p.E2187K on NM_000721.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1005165258, COSV62381751; called by mutect2, varscan2
- CACNA1F | c.5885T>A p.F1962Y | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.039); catalogued as COSV99603087; called by muse, mutect2, varscan2
- CACNA1G | c.1759G>A p.G587R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs770071496, COSV61732066; called by mutect2, varscan2
- CACNA1H | c.6589C>T p.P2197S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746807446, COSV52357109; called by muse, mutect2, varscan2
- CACNA1H | c.6875C>T p.S2292F | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52353437; called by muse, mutect2, varscan2
- CACNA1I | c.4705G>A p.E1569K | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60818011; called by muse, mutect2, varscan2
- CACNA2D2 | c.328A>T p.N110Y | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56568866; called by muse, mutect2, varscan2
- CACNA2D3 | c.2437C>T p.P813S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as rs746257679, COSV55578994; called by muse, mutect2, varscan2
- CAD | c.6116G>A p.R2039Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.856); catalogued as rs1433885288, COSV53031514; called by muse, mutect2, varscan2
- CADPS2 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV57384259; called by muse, mutect2, varscan2
- CALCRL | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.286); catalogued as COSV66477275; called by muse, mutect2, varscan2
- CALR3 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV54172005; called by muse, mutect2, varscan2
- CALU | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50823314; called by muse, mutect2, varscan2
- CAMK1 | c.216G>A p.K72= | Splice Region (SNP) | VAF 32/135 reads (24%) | catalogued as COSV56539839; called by muse, mutect2, varscan2
- CAMK1D | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs148446769; called by muse, mutect2, varscan2
- CAPN10 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV54379587; called by muse, mutect2, varscan2
- CAPN13 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV54435054; called by muse, mutect2, varscan2
- CAPN6 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 95/195 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as COSV60693652; called by muse, varscan2
- CAPN9 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202096741, COSV55239322; called by mutect2, varscan2
- CAPRIN2 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.494); catalogued as COSV51835333; called by muse, mutect2, varscan2
- CAPZA3 | c.510G>A p.W170* | Nonsense Mutation (SNP) | VAF 25/40 reads (63%) | catalogued as rs868010711, COSV56850834; called by muse, mutect2, varscan2
- CARMIL1 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61523443; called by muse, mutect2, varscan2
- CASKIN2 | c.209A>T p.E70V | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58693084; called by mutect2, varscan2
- CASR | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.173); catalogued as COSV56141175; called by muse, varscan2
- CASR | c.1516A>G p.N506D (on ENST00000490131; = p.N583D on NM_000388.4) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56141181; called by muse, mutect2, varscan2
- CATSPERB | c.2133G>A p.W711* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as COSV56434562; called by muse, mutect2, varscan2
- CBLB | c.590T>A p.F197Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51436277; called by mutect2, varscan2
- CBLC | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1035887672, COSV54326028; called by muse, varscan2
- CBLL2 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV60369355; called by mutect2, varscan2
- CC2D1A | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58786082; called by muse, mutect2, varscan2
- CCDC105 | c.939A>T p.E313D | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV52965582; called by muse, mutect2, varscan2
- CCDC63 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs1221505795, COSV57527710, COSV57530943; called by muse, mutect2, varscan2
- CCDC8 | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV56774955; called by muse, mutect2, varscan2
- CCKAR | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55163829; called by muse, mutect2, varscan2
- CCL7 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs149253093; called by muse, mutect2, varscan2
- CCR1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as COSV56122989; called by muse, mutect2, varscan2
- CCR3 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as rs754911047, COSV62462585; called by mutect2, varscan2
- CCR9 | c.969A>T p.R323S (on ENST00000357632 / NM_031200.3; = p.R311S on NM_006641.4) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV62940768; called by muse, mutect2, varscan2
- CD163L1 | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as rs766336616, COSV58016401; called by mutect2, varscan2
- CD163L1 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as COSV100550628; called by muse, mutect2, varscan2
- CD163L1 | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.036); catalogued as COSV100550629; called by muse, mutect2, varscan2
- CD209 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773126419, COSV52658491; called by muse, mutect2, varscan2
- CD22 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50067056; called by mutect2, varscan2
- CD300LB | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.28); catalogued as rs1409718703, COSV58725463, COSV58726417; called by muse, mutect2, varscan2
- CD5 | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs1286665943, COSV100759769; called by muse, varscan2
- CD5 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV100759897; called by muse, varscan2
- CD72 | c.711G>A p.W237* | Nonsense Mutation (SNP) | VAF 48/71 reads (68%) | catalogued as COSV52412409; called by muse, mutect2, varscan2
- CD86 | c.212G>A p.G71D (on ENST00000330540 / NM_175862.5; = p.G65D on NM_006889.4) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52609345, COSV52610094; called by muse, mutect2, varscan2
- CDC34 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 94/403 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53118129; called by muse, mutect2, varscan2
- CDH11 | c.2101C>T p.Q701* | Nonsense Mutation (SNP) | VAF 35/114 reads (31%) | catalogued as COSV51776473; called by muse, mutect2, varscan2
- CDH11 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs185190786, COSV51763570; called by mutect2, varscan2
- CDH9 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 72/107 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs558544451, COSV50254945, COSV50256906; called by muse, mutect2, varscan2
- CDK18 | c.1457G>A p.R486Q (on ENST00000506784 / NM_212503.3; = p.R456Q on NM_002596.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs575337018, COSV63728816; called by mutect2, varscan2
- CDKN1A | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV55191385; called by mutect2, varscan2
- CDYL2 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs773366284, COSV73654904; called by mutect2, varscan2
- CEACAM18 | c.713A>C p.D238A | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV67284020; called by muse, mutect2, varscan2
- CEACAM5 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs782578740, COSV55754878; called by muse, mutect2, varscan2
- CEACAM6 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV52269157; called by muse, mutect2, varscan2
- CEACAM7 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555810905, COSV50074636; called by muse, mutect2, varscan2
- CECR2 | c.2020C>T p.P674S (on ENST00000342247 / NM_001290047.2; = p.P491S on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52847732; called by muse, mutect2
- CELA1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs376966959; called by mutect2, varscan2
- CELA2B | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV65546294; called by muse, varscan2
- CELA3B | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV61405517; called by muse, mutect2, varscan2
- CEP112 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | catalogued as COSV67144574; called by muse, mutect2, varscan2
- CEP83 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV51583376; called by muse, mutect2
- CERKL | c.1228C>T p.P410S (on ENST00000339098 / NM_001030311.2; = p.P384S on NM_201548.5) | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as COSV59213270, COSV59215588; called by muse, varscan2
- CFAP221 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as COSV54659789, COSV99732053; called by mutect2, varscan2
- CFAP299 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.259); catalogued as rs757771954, COSV63881313; called by mutect2, varscan2
- CFAP43 | c.4522G>A p.E1508K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as COSV63854930; called by muse, mutect2, varscan2
- CFAP43 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.175); catalogued as rs1348848635, COSV53377669; called by muse, mutect2, varscan2
- CFAP43 | c.2437G>A p.G813R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV53381045; called by muse, mutect2, varscan2
- CFAP43 | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53381054; called by muse, mutect2, varscan2
- CFAP47 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52884843, COSV52891359; called by muse, mutect2, varscan2
- CFAP47 | c.1633A>C p.K545Q | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52891377; called by muse, mutect2, varscan2
- CFAP54 | c.4781C>T p.S1594L | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV61575035; called by muse, mutect2, varscan2
- CFAP54 | c.7615C>T p.P2539S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV61575040; called by muse, mutect2, varscan2
- CFAP58 | c.204T>A p.N68K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV57213537; called by muse, varscan2
- CFAP65 | c.2816G>A p.R939K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV58565957; called by muse, varscan2
- CFAP70 | c.2633C>T p.S878L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV60286695; called by mutect2, varscan2
- CFAP92 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV54048810; called by muse, mutect2, varscan2
- CFH | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62778582, COSV62778782; called by muse, mutect2, varscan2
- CFH | c.2684C>T p.T895I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as COSV66413070; called by muse, mutect2, varscan2
- CFTR | c.3823G>A p.D1275N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50042333; called by muse, mutect2, varscan2
- CGB3 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 36/209 reads (17%) | catalogued as COSV62164704; called by muse, mutect2, varscan2
- CHAF1B | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58439478; called by muse, mutect2, varscan2
- CHD4 | c.494A>T p.H165L | Missense Mutation (SNP) | VAF 88/325 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.085); catalogued as COSV58910269; called by muse, mutect2, varscan2
- CHD7 | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71114305; called by mutect2, varscan2
- CHD8 | c.3427C>T p.P1143S (on ENST00000646647 / NM_001170629.2; = p.P864S on NM_020920.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101303207; called by muse, mutect2, varscan2
- CHD9 | c.7861C>T p.P2621S (on ENST00000398510 / NM_001382353.1; = p.P2605S on NM_025134.7) | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54616019; called by muse, mutect2, varscan2
- CHIA | c.1274G>A p.G425E (on ENST00000343320; = p.G317E on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV58478051; called by mutect2, varscan2
- CHMP4C | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV51926202; called by mutect2, varscan2
- CHRDL1 | c.929G>A p.G310E (on ENST00000372045; = p.G316E on NM_145234.4) | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54327303; called by muse, mutect2, varscan2
- CHST11 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as COSV57994193; called by muse, mutect2, varscan2
- CHST5 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1389703147, COSV60338479; called by mutect2, varscan2
- CHSY1 | c.1262A>G p.K421R | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0.023); catalogued as rs1311709028, COSV54255852; called by muse, mutect2, varscan2
- CIC | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs771116358, COSV50659416; called by muse, mutect2, varscan2
- CLDN7 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1379386241, COSV63040184; called by muse, mutect2, varscan2
- CLEC18B | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as rs1254174212; called by mutect2, varscan2
- CLEC3A | c.508G>A p.G170S (on ENST00000651443; = p.G161S on NM_005752.6) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs762436240, COSV55223588; called by muse, mutect2, varscan2
- CLEC4D | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs199971365, COSV55230793; called by mutect2, varscan2
- CLEC4E | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55225024; called by muse, mutect2, varscan2
- CLSTN2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV71724767; called by muse, mutect2, varscan2
- CLTB | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765062245, COSV60045473; called by muse, mutect2, varscan2
- CNBD2 | c.1482G>A p.W494* (on ENST00000373973 / NM_001365709.1; = p.W490* on NM_080834.4) | Nonsense Mutation (SNP) | VAF 40/174 reads (23%) | catalogued as rs1568939472, COSV62587930; called by muse, mutect2, varscan2
- CNDP1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1413305723, COSV62595233; called by muse, mutect2, varscan2
- CNGA1 | c.1032A>T p.K344N | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV62056804; called by muse, mutect2, varscan2
- CNGA2 | c.1205G>A p.S402N | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV61706199; called by muse, mutect2, varscan2
- CNOT3 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV55368172; called by muse, mutect2, varscan2
- CNTN5 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201638465, COSV54278829; called by mutect2, varscan2
- CNTN6 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV63163412; called by mutect2, varscan2
- CNTNAP2 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62231631; called by muse, mutect2, varscan2
- CNTNAP2 | c.1930T>G p.L644V | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV62163553, COSV62251008; called by muse, mutect2, varscan2
- CNTNAP3 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1427108514, COSV52665237; called by mutect2, varscan2
- CNTNAP3 | c.1729G>A p.G577S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs766323682, COSV52675212; called by mutect2, varscan2
- CNTNAP4 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs764763387, COSV56673375; called by mutect2, varscan2
- COA7 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV101034466; called by mutect2, varscan2
- COA7 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV65299243; called by muse, mutect2, varscan2
- COBL | c.3071C>T p.P1024L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54357373; called by muse, mutect2, varscan2
- COL11A1 | c.3089G>T p.G1030V | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62196220; called by mutect2, varscan2
- COL12A1 | c.7251G>A p.W2417* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV59407190; called by muse, mutect2, varscan2
- COL15A1 | c.3423G>A p.M1141I | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV66647764, COSV66648968; called by muse, mutect2, varscan2
- COL16A1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54701499; called by muse, mutect2, varscan2
- COL17A1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62229255; called by muse, mutect2, varscan2
- COL19A1 | c.2669G>A p.G890E | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59587181; called by muse, mutect2, varscan2
- COL1A2 | c.3007G>A p.G1003S | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51965631; called by muse, mutect2, varscan2
- COL1A2 | c.3935T>C p.V1312A | Missense Mutation (SNP) | VAF 59/62 reads (95%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV51965638; called by muse, mutect2, varscan2
- COL21A1 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55152222; called by muse, mutect2, varscan2
- COL22A1 | c.2592+2T>G p.X864_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV57336810, COSV57358878; called by muse, varscan2
- COL24A1 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209130574, COSV65313551; called by muse, mutect2, varscan2
- COL27A1 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as rs745882834, COSV61930532; called by muse, mutect2, varscan2
- COL3A1 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as rs1021622002, COSV58585743; called by mutect2, varscan2
- COL4A4 | c.3100T>C p.S1034P | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV61636290; called by muse, mutect2, varscan2
- COL4A5 | c.4873C>T p.R1625C | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865842167, COSV60362202; called by muse, mutect2, varscan2
- COL5A1 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs763456705, COSV65666677, COSV65674292; ClinVar: uncertain significance; called by mutect2, varscan2
- COL5A1 | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs866766228, COSV65674298; called by mutect2, varscan2
- COL6A3 | c.7514G>A p.G2505E | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99801188; called by muse, mutect2, varscan2
- COL7A1 | c.5246G>A p.G1749E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60402588; called by muse, mutect2, varscan2
- COL7A1 | c.4229C>T p.P1410L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1417358926, COSV60391009; called by muse, mutect2, varscan2
- COL8A2 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV57443342; called by mutect2, varscan2
- COLEC10 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60522781; called by muse, mutect2, varscan2
- COLGALT2 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62300605; called by muse, mutect2, varscan2
- COQ8B | c.891C>T p.F297= | Splice Region (SNP) | VAF 26/116 reads (22%) | catalogued as COSV54688915; called by mutect2, varscan2
- CP | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs886058089, COSV52833619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA3 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs755054597, COSV56047224; called by muse, mutect2, varscan2
- CPAMD8 | c.3404G>A p.R1135Q (on ENST00000651564; = p.R1088Q on NM_015692.5) | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs61742969, COSV71595756; called by muse, mutect2, varscan2
- CR1 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.528); catalogued as COSV65462852; called by muse, mutect2, varscan2
- CRB2 | c.2276G>A p.W759* | Nonsense Mutation (SNP) | VAF 27/134 reads (20%) | catalogued as COSV63505388; called by muse, mutect2, varscan2
- CREBRF | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.059); catalogued as COSV51636249; called by muse, mutect2, varscan2
- CRYZ | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778335759, COSV61718563; called by mutect2, varscan2
- CSF1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 72/118 reads (61%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as rs755112511, COSV60035282; called by muse, mutect2, varscan2
- CSHL1 | c.471+1G>A p.X157_splice (on ENST00000309894 / NM_022581.3; = p.X63_splice on NM_001318.4) | Splice Site (SNP) | VAF 19/110 reads (17%) | catalogued as COSV51989942; called by muse, mutect2, varscan2
- CSMD1 | c.4559G>A p.G1520E (on ENST00000520002; = p.G1519E on NM_033225.6) | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59379247; called by muse, mutect2, varscan2
- CSMD1 | c.3212C>T p.S1071F (on ENST00000520002; = p.S1070F on NM_033225.6) | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs368592556, COSV59302376; called by muse, mutect2, varscan2
- CSMD2 | c.5366C>T p.A1789V | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53925946; called by muse, mutect2, varscan2
- CSMD3 | c.5812C>T p.P1938S (on ENST00000297405 / NM_001363185.1; = p.P1834S on NM_052900.3) | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV52308278; called by muse, varscan2
- CSMD3 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52308297; called by muse, mutect2
- CSMD3 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 128/176 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV52114257; called by muse, mutect2, varscan2
- CT83 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV64141462; called by mutect2, varscan2
- CTNND2 | c.3417G>A p.Q1139= | Splice Region (SNP) | VAF 39/131 reads (30%) | catalogued as COSV58925123, COSV58931947; called by muse, mutect2, varscan2
- CTNND2 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV58925134; called by mutect2, varscan2
- CYFIP2 | c.2408C>T p.S803F (on ENST00000616178 / NM_001291722.2; = p.S778F on NM_014376.4) | Missense Mutation (SNP) | VAF 160/507 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59049967; called by muse, mutect2, varscan2
- CYP26C1 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.035); catalogued as rs979419105, COSV99592476; called by muse, mutect2
- CYP2B6 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as rs993074326, COSV57845353; called by muse, mutect2, varscan2
- CYP2C18 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53674953; called by muse, mutect2, varscan2
- CYP2C19 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs867860347, COSV64908478, COSV64909232; called by muse, mutect2, varscan2
- CYP2C9 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV53252507; called by muse, varscan2
- CYP2C9 | c.332-1G>A p.X111_splice | Splice Site (SNP) | VAF 14/27 reads (52%) | catalogued as COSV53252532; called by muse, varscan2
- CYP2C9 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs562386989, COSV53246350; called by muse, mutect2, varscan2
- CYP4F12 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs763786060, COSV61173292; called by muse, mutect2, varscan2
- CYP4Z1 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.403); catalogued as COSV61965871, COSV61966430; called by muse, mutect2, varscan2
- CYP7B1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394828774, COSV59582859; called by mutect2, varscan2
- DAG1 | c.2672C>T p.P891L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194422667, COSV100444911, COSV58187002; called by muse, mutect2, varscan2
- DAPK1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767507074, COSV100802699, COSV63793895; called by mutect2, varscan2
- DAXX | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV56472474; called by muse, mutect2, varscan2
- DCLK2 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs751438505, COSV56211717; called by mutect2, varscan2
- DDIAS | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61273193; called by muse, mutect2, varscan2
- DDX24 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1448635179, COSV58213763; called by muse, mutect2, varscan2
- DDX41 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV57254395; called by muse, mutect2, varscan2
- DEFA3 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.951); catalogued as COSV100590593; called by mutect2, varscan2
- DEFA4 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); catalogued as rs770482785, COSV52405324; called by mutect2, varscan2
- DEFB132 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66677412; called by mutect2, varscan2
- DELE1 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52006496; called by muse, mutect2, varscan2
- DENND2C | c.2651G>A p.R884Q (on ENST00000393274 / NM_001256404.2; = p.R827Q on NM_198459.4) | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs779144796, COSV67923963; called by muse, varscan2
- DENND2D | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV62960008; called by muse, mutect2, varscan2
- DENND3 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs752026665, COSV52804175; called by mutect2, varscan2
- DGKB | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV51816527; called by muse, mutect2, varscan2
- DGKE | c.284A>C p.D95A | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV52351342; called by muse, mutect2, varscan2
- DGKG | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.036); catalogued as rs776905756, COSV53965478; called by mutect2, varscan2
- DGKI | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV55973775; called by muse, mutect2, varscan2
- DHCR7 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62796625; called by muse, mutect2, varscan2
- DHX36 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57677063; called by muse, mutect2, varscan2
- DHX57 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54890854; called by muse, mutect2, varscan2
- DIAPH1 | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.466); catalogued as rs755863519, COSV53888448, COSV99526108; called by muse, mutect2, varscan2
- DIRAS2 | c.592A>C p.I198L | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV65370752; called by muse, mutect2, varscan2
- DIRAS2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65370755; called by muse, mutect2, varscan2
- DISP3 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV53836794; called by muse, mutect2, varscan2
- DLG2 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs747445340, COSV54682552; called by muse, mutect2, varscan2
- DLG5 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs758386827, COSV64949893; called by muse, varscan2
- DLGAP3 | c.554A>C p.H185P | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52397407; called by muse, mutect2, varscan2
- DLL4 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99989991; called by muse, mutect2, varscan2
- DMBT1 | c.3146G>A p.G1049D (on ENST00000338354 / NM_001377530.1; = p.G550D on NM_004406.3) | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV57539213; called by muse, mutect2, varscan2
- DMBT1 | c.5594G>A p.G1865D (on ENST00000338354 / NM_001377530.1; = p.G1108D on NM_004406.3) | Missense Mutation (SNP) | VAF 60/85 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57560410; called by muse, mutect2, varscan2
- DMRTB1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as rs1462302710, COSV65113980; called by muse, mutect2, varscan2
- DMXL2 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143486672, COSV51843689; called by mutect2, varscan2
- DNAH10 | c.5833G>A p.D1945N (on ENST00000409039; = p.D1884N on NM_207437.3) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101292264, COSV69000857, COSV69004213; called by mutect2, varscan2
- DNAH10 | c.6023C>T p.S2008L (on ENST00000409039; = p.S1947L on NM_207437.3) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs747425107, COSV69000866; called by mutect2, varscan2
- DNAH10 | c.10406G>A p.W3469* (on ENST00000409039; = p.W3408* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV69000890; called by muse, mutect2, varscan2
- DNAH11 | c.10441G>A p.E3481K | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs727502969, COSV60950892; ClinVar: uncertain significance; called by mutect2, varscan2
- DNAH11 | c.12331G>A p.G4111R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV60979535; called by muse, mutect2, varscan2
- DNAH17 | c.3175C>T p.H1059Y | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs1030104038, COSV67760706; called by muse, varscan2
- DNAH17 | c.3122C>T p.S1041F | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV67749927; called by muse, varscan2
- DNAH3 | c.11882C>T p.P3961L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770414; called by muse, mutect2, varscan2
- DNAH3 | c.11881C>T p.P3961S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770417; called by muse, mutect2, varscan2
- DNAH5 | c.12499G>A p.G4167S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs1313629907, COSV54250052; called by muse, varscan2
- DNAH5 | c.12460C>T p.P4154S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1012746507, COSV54250060; called by muse, varscan2
- DNAH5 | c.12033G>A p.Q4011= | Splice Region (SNP) | VAF 8/35 reads (23%) | catalogued as COSV54250070; called by muse, varscan2
- DNAH5 | c.11995C>T p.L3999F | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1223520112, COSV54250078; called by muse, varscan2
- DNAH5 | c.10306C>T p.R3436C | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs774231638, COSV54237891; called by mutect2, varscan2
- DNAH5 | c.9706G>A p.D3236N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs374206128, COSV99451113; called by mutect2, varscan2
- DNAH5 | c.9146A>T p.N3049I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs868564572, COSV54250103; called by muse, varscan2
- DNAH5 | c.7399C>T p.P2467S | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV54245960, COSV54249052; called by muse, mutect2, varscan2
- DNAH5 | c.5146C>T p.R1716W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368644722, CM091941, COSV99450142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.779G>T p.W260L | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54221661, COSV54250132; called by mutect2, varscan2
- DNAH5 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV54220751, COSV54250140; called by muse, mutect2, varscan2
- DNAH7 | c.2012G>A p.R671K | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV56762401; called by muse, mutect2, varscan2
- DNAH8 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756498084, COSV59439392; called by muse, mutect2, varscan2
- DNAH8 | c.2133C>T p.I711= | Splice Region (SNP) | VAF 16/34 reads (47%) | catalogued as COSV59444212; called by mutect2, varscan2
- DNAH8 | c.6095G>A p.G2032E | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59478418; called by muse, mutect2, varscan2
- DNAH9 | c.13370G>A p.G4457E | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1430722938, COSV52375217; called by muse, mutect2, varscan2
- DNAI4 | c.645T>A p.D215E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV64019882; called by muse, mutect2, varscan2
- DNAJB7 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 62/449 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV53423719; called by muse, mutect2, varscan2
- DNM1 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.56); catalogued as COSV57855846; called by muse, mutect2, varscan2
- DNM3 | c.1885G>A p.A629T (on ENST00000355305 / NM_001350206.2; = p.A619T on NM_015569.5) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs940565036, COSV62466626; called by muse, mutect2, varscan2
- DNMT3A | c.1342T>C p.Y448H | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as COSV53076583; called by muse, mutect2, varscan2
- DNMT3B | c.2333C>T p.S778L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV52415479; called by muse, mutect2, varscan2
- DOK6 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs572815383, COSV66937259; called by muse, mutect2, varscan2
- DPP10 | c.608A>C p.Q203P | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.609); catalogued as COSV59723452; called by muse, mutect2, varscan2
- DPRX | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs769091377, COSV64949952; called by muse, mutect2, varscan2
- DPY19L4 | c.1964G>A p.R655K | Missense Mutation (SNP) | VAF 155/516 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV68963751; called by muse, mutect2, varscan2
- DPYSL4 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV58309804; called by muse, mutect2, varscan2
- DSC1 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV57151137; called by mutect2, varscan2
- DSC3 | c.1520G>A p.R507K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.381); catalogued as rs747176017, COSV64575246; called by muse, mutect2, varscan2
- DSC3 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs964947988, COSV64575251; called by muse, mutect2, varscan2
- DSE | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV59064375; called by muse, mutect2, varscan2
- DSG3 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV57123918; called by muse, mutect2, varscan2
- DSP | c.3935C>T p.S1312F | Missense Mutation (SNP) | VAF 99/150 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV65795685; called by muse, mutect2, varscan2
- DUOX1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1296574864, COSV58486164; called by mutect2, varscan2
- DUSP10 | c.80T>G p.L27* | Nonsense Mutation (SNP) | VAF 35/204 reads (17%) | catalogued as COSV100100778; called by muse, mutect2, varscan2
- DUSP10 | c.79T>G p.L27V | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.952); catalogued as COSV100100780; called by muse, mutect2, varscan2
- E2F8 | c.2599C>T p.H867Y | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV51466059; called by muse, mutect2, varscan2
- EBF1 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58194031; called by muse, mutect2, varscan2
- EFCAB12 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV58178615; called by muse, mutect2, varscan2
- EFHD2 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766071328, COSV65658296; called by muse, varscan2
- EFS | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as COSV52837316; called by muse, mutect2, varscan2
- EFTUD2 | c.2758C>T p.P920S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV53656313; called by muse, mutect2, varscan2
- EIF3A | c.3473C>T p.P1158L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.444); catalogued as COSV100974794; called by muse, mutect2, varscan2
- EIF3A | c.3472C>T p.P1158S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); catalogued as COSV100974804, COSV64961671; called by muse, mutect2, varscan2
- EIF3D | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV53405164; called by muse, mutect2, varscan2
- ELMO1 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1339960421, COSV60323352; called by mutect2, varscan2
- ELOA2 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 95/153 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV55308068; called by muse, mutect2, varscan2
- ELOA3 | c.958A>T p.M320L | Missense Mutation (SNP) | VAF 70/879 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV55308062; called by muse, varscan2
- ELP3 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs367635310; called by muse, mutect2, varscan2
- EMILIN3 | c.1391G>A p.G464D | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60038633; called by muse, mutect2, varscan2
- ENPP3 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.279); catalogued as COSV62956486; called by muse, mutect2, varscan2
- EOGT | c.1241G>A p.R414K (on ENST00000383701 / NM_001278689.2; = p.R330K on NM_173654.3) | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV55153622; called by muse, mutect2, varscan2
- EP300 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54344469; called by muse, mutect2, varscan2
- EP400 | c.8075C>T p.S2692F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV57785505; called by muse, mutect2, varscan2
- EPG5 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99957762; called by muse, mutect2, varscan2
- EPG5 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868443599, COSV56355670; called by muse, mutect2, varscan2
- EPHA10 | c.2627A>G p.H876R | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57627028; called by muse, mutect2, varscan2
- EPHA4 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 172/409 reads (42%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.717); catalogued as rs868224085, COSV56043572; called by muse, varscan2
- EPHA7 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1256527658, COSV65191152, COSV65194854; called by muse, mutect2, varscan2
- EPHA7 | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV65170437, COSV65170537; called by muse, varscan2
- EPHB1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV67670593; called by muse, mutect2, varscan2
- EPPK1 | c.6524A>G p.Q2175R | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.02); catalogued as rs1554659147, COSV73262343; called by muse, mutect2, varscan2
- EPRS1 | c.2168C>G p.A723G | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV65101430; called by muse, mutect2, varscan2
- EPS8L2 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs776268694, COSV59350144; called by mutect2, varscan2
- EPS8L3 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV62609542; called by mutect2, varscan2
- ERBB4 | c.3350C>T p.P1117L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs771882543, COSV61520368; called by muse, mutect2, varscan2
- ERICH3 | c.4042G>A p.E1348K | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.017); catalogued as COSV58607699; called by muse, mutect2, varscan2
- ERICH3 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs766243088, COSV58617523; called by muse, mutect2, varscan2
- ERLEC1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs1340719040, COSV51753529; called by muse, mutect2, varscan2
- ESR1 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52783819; called by muse, mutect2, varscan2
- EVPL | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767324618, COSV56908538; called by mutect2, varscan2
- EXD3 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.686); catalogued as COSV59813203; called by muse, mutect2, varscan2
- EYA2 | c.89G>A p.W30* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100427297; called by mutect2, varscan2
- EYA2 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100427298; called by muse, mutect2, varscan2
- F2RL2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 87/144 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56972004; called by muse, mutect2, varscan2
- FAM135B | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52751720; called by muse, mutect2, varscan2
- FAM135B | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as COSV52712421; called by muse, mutect2, varscan2
- FAM13B | c.1525C>T p.H509Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as COSV50373399; called by muse, mutect2, varscan2
- FAM155B | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52937696; called by muse, mutect2, varscan2
- FAM161A | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 47/96 reads (49%) | catalogued as rs764845483, COSV56766769; called by muse, mutect2, varscan2
- FAM171A1 | c.2132C>T p.S711F | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867331185, COSV65313805; called by muse, mutect2, varscan2
- FAM171B | c.1160A>T p.K387I | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV59008319; called by mutect2, varscan2
- FAM184A | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); catalogued as rs1366638928, COSV58858510; called by muse, mutect2, varscan2
- FAM71B | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 134/513 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as rs543304286, COSV57229990; called by muse, mutect2, varscan2
- FAM71C | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as rs924327345, COSV60944351; called by muse, mutect2, varscan2
- FAM83C | c.513G>A p.T171= | Splice Region (SNP) | VAF 34/124 reads (27%) | catalogued as rs776690764, COSV65584374; called by muse, mutect2, varscan2
- FAM83D | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV54157782; called by muse, mutect2, varscan2
- FANCB | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.382); catalogued as COSV60761688; called by muse, mutect2
- FANCG | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV66214151; called by muse, mutect2, varscan2
- FAT2 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as COSV55818247; called by muse, mutect2, varscan2
- FAT3 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 124/255 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); catalogued as rs367795074, COSV53113596; called by muse, mutect2, varscan2
- FAT3 | c.7628G>A p.R2543Q | Missense Mutation (SNP) | VAF 126/310 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as rs1234031232, COSV53075769; called by muse, mutect2, varscan2
- FAT4 | c.10891C>T p.P3631S | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV58672554; called by muse, mutect2, varscan2
- FBLN2 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as rs769023820, COSV55482554; called by muse, mutect2, varscan2
- FBLN5 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs201191163, COSV50909197; called by muse, varscan2
- FBN1 | c.8203G>A p.E2735K | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs756124960, COSV57329343; called by mutect2, varscan2
- FBN2 | c.3187G>A p.D1063N | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV52543694; called by muse, mutect2, varscan2
- FBXO33 | c.1472C>T p.T491I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV53235895; called by muse, mutect2, varscan2
- FBXO36 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99391881; called by muse, mutect2, varscan2
- FBXW8 | c.1469C>T p.P490L (on ENST00000309909; = p.P528L on NM_012174.1) | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59303224; called by muse, mutect2, varscan2
- FCGBP | c.6734C>T p.S2245F | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99663948; called by muse, varscan2
- FCRL2 | c.676T>G p.C226G | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63835025; called by muse, mutect2, varscan2
- FCRL3 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63844748; called by muse, mutect2, varscan2
- FHOD1 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV50768669; called by mutect2, varscan2
- FLG | c.10694G>A p.G3565E | Missense Mutation (SNP) | VAF 56/391 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64248401; called by muse, mutect2, varscan2
- FLNC | c.6989G>A p.G2330D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV57964234; called by muse, mutect2, varscan2
- FLRT1 | c.1474T>C p.Y492H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV55367063; called by muse, mutect2, varscan2
- FLT1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV56728855; called by muse, mutect2, varscan2
- FMO2 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52946544; called by muse, mutect2
- FMO3 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777342108, COSV63008492; called by mutect2, varscan2
- FNDC1 | c.4238G>A p.R1413Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV51936141; called by mutect2, varscan2
- FNDC1 | c.5323G>A p.D1775N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.335); catalogued as COSV51947426; called by mutect2, varscan2
- FOXN2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61318642; called by muse, mutect2, varscan2
- FOXO3 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752765431, COSV59631110; called by muse, mutect2
- FOXP2 | c.1924C>T p.H642Y | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV63493555; called by muse, mutect2, varscan2
- FREM1 | c.4540G>A p.G1514R | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs267602183, COSV66529830; called by muse, mutect2, varscan2
- FRMD5 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68725205; called by muse, mutect2, varscan2
- FRMD7 | c.1810G>A p.G604R | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53748608; called by muse, mutect2, varscan2
- FRMD7 | c.1257G>A p.M419I | Missense Mutation (SNP) | VAF 105/108 reads (97%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53748619; called by muse, mutect2, varscan2
- FRMD7 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1365805940, COSV53745294; called by mutect2, varscan2
- FRMPD1 | c.3815C>T p.S1272L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.374); catalogued as COSV66702942; called by mutect2, varscan2
- FRMPD4 | c.3380A>T p.E1127V | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.107); catalogued as COSV66222746; called by muse, mutect2, varscan2
- FUT10 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs149780215; called by muse, mutect2, varscan2
- FUT3 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.903); catalogued as COSV54608320; called by muse, mutect2, varscan2
- FYB2 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV58589004; called by muse, mutect2, varscan2
- FYB2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58582687; called by muse, mutect2, varscan2
- GABRA3 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV64804824; called by muse, mutect2, varscan2
- GABRA3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 84/90 reads (93%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as COSV64804833; called by muse, varscan2
- GABRA6 | c.39-1G>A p.X13_splice | Splice Site (SNP) | VAF 18/48 reads (38%) | catalogued as COSV50884229, COSV99194776; called by muse, varscan2
- GABRG3 | c.222C>G p.D74E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as COSV61510806, COSV61532494; called by muse, mutect2, varscan2
- GALNT14 | c.1381-1G>A p.X461_splice | Splice Site (SNP) | VAF 19/114 reads (17%) | catalogued as COSV61110747; called by muse, mutect2, varscan2
- GALNT8 | c.1126G>A p.G376S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as COSV52901473; called by muse, mutect2, varscan2
- GALNTL6 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1011629190, COSV72491025, COSV72493992; called by mutect2, varscan2
- GBP1 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 64/547 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV100976301; called by muse, mutect2, varscan2
- GBP1 | c.1632A>C p.K544N | Missense Mutation (SNP) | VAF 63/557 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.127); catalogued as COSV100976302; called by muse, mutect2, varscan2
- GCA | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV52025528; called by muse, mutect2, varscan2
- GCDH | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs201714645, COSV53368504; called by muse, mutect2, varscan2
- GCG | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV64962190; called by muse, mutect2, varscan2
- GCSAM | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.822); catalogued as rs1335754812, COSV58264479; called by muse, mutect2, varscan2
- GFRAL | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs753873571, COSV61231413, COSV61231877; called by mutect2, varscan2
- GGA3 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99821723; called by muse, mutect2
- GGTLC1 | c.459G>A p.W153* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as rs974767971, COSV53850369; called by muse, mutect2, varscan2
- GHITM | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV64539203; called by muse, mutect2, varscan2
- GIMAP5 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as COSV57530455; called by muse, mutect2, varscan2
- GIMAP6 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as COSV61034699; called by muse, mutect2, varscan2
- GIMAP6 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773075886, COSV61034706; called by muse, mutect2, varscan2
- GIMAP7 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV57960511; called by muse, mutect2, varscan2
- GJA1 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as rs1562174474, COSV56999504; called by muse, mutect2, varscan2
- GJA4 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60726051; called by muse, mutect2, varscan2
- GJB5 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58355424; called by muse, mutect2, varscan2
- GLI3 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV67894555; called by muse, mutect2, varscan2
- GLP2R | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.624); catalogued as rs1567726204, COSV52329243; called by muse, mutect2, varscan2
- GLP2R | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV52325851; called by mutect2, varscan2
- GLRA1 | c.50T>C p.F17S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.132); catalogued as rs376426309; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GLRB | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52422109; called by muse, mutect2, varscan2
- GLYATL1 | c.493G>A p.E165K (on ENST00000317391 / NM_001354699.1; = p.E196K on NM_080661.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.165); catalogued as COSV55611249; called by mutect2, varscan2
- GMPS | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs1482886098, COSV55809590; called by muse, varscan2
- GOLGB1 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.295); catalogued as COSV61465819; called by muse, mutect2, varscan2
- GOLPH3L | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1414115535, COSV55047774; called by muse, mutect2, varscan2
- GP2 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs140222432, COSV56893728; called by mutect2, varscan2
- GPD1 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56549092; called by muse, mutect2, varscan2
- GPR158 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV66281682; called by mutect2, varscan2
- GPR171 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.992); catalogued as COSV56380632, COSV56390982; called by mutect2, varscan2
- GPR39 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61428641; called by muse, mutect2, varscan2
- GPRIN2 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV65402523; called by muse, mutect2, varscan2
- GRAMD2B | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53509966; called by muse, mutect2, varscan2
- GRB14 | c.1221+1G>A p.X407_splice | Splice Site (SNP) | VAF 48/91 reads (53%) | catalogued as COSV55743046; called by muse, mutect2, varscan2
- GRHL3 | c.667G>A p.D223N (on ENST00000350501 / NM_198174.3; = p.D228N on NM_021180.3) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV99359669; called by muse, mutect2, varscan2
- GRIA1 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs867292089, COSV53601780; called by muse, mutect2, varscan2
- GRIA1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377273074; called by mutect2, varscan2
- GRIK1 | c.2424G>A p.M808I | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV58731178; called by mutect2, varscan2
- GRIK5 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1555871620, COSV53485298; called by muse, mutect2, varscan2
- GRIN2A | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58032210, COSV58055529; called by muse, mutect2, varscan2
- GRIN2B | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 114/182 reads (63%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.526); catalogued as COSV74207623; called by muse, mutect2, varscan2
- GRIN2B | c.1048T>A p.S350T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV74207624; called by muse, mutect2, varscan2
- GRIN2B | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs867779077, COSV74206078; called by mutect2, varscan2
- GRK4 | c.629G>A p.G210E (on ENST00000398052 / NM_182982.3; = p.G178E on NM_005307.3) | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61671003; called by muse, mutect2, varscan2
- GRM1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV51303899; called by muse, mutect2, varscan2
- GRXCR1 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV67674524; called by muse, mutect2, varscan2
- GSDMA | c.753G>A p.G251= | Splice Region (SNP) | VAF 9/20 reads (45%) | catalogued as COSV56975557; called by muse, mutect2, varscan2
- GSDME | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV61652525, COSV61652833; called by muse, mutect2, varscan2
- GSDME | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV61652838; called by muse, mutect2, varscan2
- GSN | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV57998823, COSV58001210; called by muse, mutect2, varscan2
- GTSF1 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as rs753855929, COSV59939434; called by muse, mutect2, varscan2
- GUCY1A1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV56656244; called by muse, mutect2, varscan2
- GUCY2C | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV99664086; called by mutect2, varscan2
- H2AC13 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100704438; called by muse, mutect2, varscan2
- H2BC1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as rs867317918, COSV51238258; called by muse, mutect2, varscan2
- HCFC1 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 52/54 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60077082, COSV60077298; called by muse, mutect2, varscan2
- HCFC1 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60077310; called by muse, mutect2, varscan2
- HCLS1 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57527310; called by muse, varscan2
- HCN1 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs773990933, COSV100302013, COSV57508684; called by muse, mutect2, varscan2
- HDC | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51080429; called by muse, mutect2, varscan2
- HECW1 | c.1798C>T p.L600F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs753677386, COSV67839342; called by mutect2, varscan2
- HELQ | c.2246A>C p.E749A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV55027773; called by muse, varscan2
- HERC5 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52038258, COSV52044686; called by mutect2, varscan2
- HLA-B | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs77659523, COSV69522992; called by muse, mutect2, varscan2
- HLA-DQB1 | c.464A>C p.Y155S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66574649; called by muse, mutect2, varscan2
- HMCN1 | c.6416A>G p.K2139R | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54938759; called by muse, mutect2, varscan2
- HNF4A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 85/326 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs748452860, COSV57382487; called by muse, mutect2, varscan2
- HNRNPK | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV61090971; called by muse, varscan2
- HOOK1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1254828908, COSV64619620; called by muse, mutect2, varscan2
- HOXA3 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57826265; called by muse, mutect2, varscan2
- HOXD13 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as rs187698441; called by mutect2, varscan2
- HP1BP3 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV104394434, COSV56564582; called by mutect2, varscan2
- HPX | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV56420516; called by muse, mutect2
- HRH3 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as COSV100420720; called by mutect2, varscan2
- HS3ST5 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1262231107, COSV57138483, COSV57141630; called by muse, mutect2, varscan2
- HUWE1 | c.3371C>T p.P1124L | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV53362763; called by muse, mutect2, varscan2
- HYDIN | c.15055G>A p.G5019R | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66642187; called by muse, mutect2, varscan2
- IFNA21 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 51/61 reads (84%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as rs755489242, COSV66518620; called by muse, mutect2, varscan2
- IGF2R | c.2596C>T p.L866F | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); catalogued as COSV100808124; called by muse, mutect2, varscan2
- IGF2R | c.4994C>T p.P1665L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV63632486; called by muse, mutect2, varscan2
- IGSF3 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs953643922, COSV59598139; called by mutect2, varscan2
- IGSF9 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0.107); catalogued as COSV63642388; called by mutect2, varscan2
- IL18R1 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52127165; called by muse, mutect2, varscan2
- IL18R1 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52127173; called by muse, mutect2, varscan2
- IL20 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs750758066, COSV65584312; called by mutect2, varscan2
- IL31 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756327888, COSV65476689; called by mutect2, varscan2
- IL5RA | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.011); catalogued as rs1181321792, COSV56526453; called by muse, mutect2, varscan2
- IMPG2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51985312; called by muse, mutect2, varscan2
- INPP5A | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61252963; called by muse, mutect2, varscan2
- INSL6 | c.391T>A p.F131I | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV67563451; called by muse, mutect2, varscan2
- INSRR | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV63877025; called by mutect2, varscan2
- IP6K1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100391369, COSV58663074; called by muse, mutect2, varscan2
- IRF2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.772); catalogued as rs1298253867, COSV66930501; called by mutect2, varscan2
- ISG15 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); catalogued as rs672601312, CM128668, COSV65106705; called by mutect2, varscan2
- ISX | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1383183657, COSV58088073, COSV58088236; called by muse, mutect2, varscan2
- ITGA1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV50896791; called by mutect2, varscan2
- ITGA1 | c.3378G>A p.E1126= | Splice Region (SNP) | VAF 53/182 reads (29%) | catalogued as rs1425630874, COSV50896930; called by muse, mutect2, varscan2
- ITGA11 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59881743; called by muse, mutect2, varscan2
- ITGA4 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1274214853, COSV52003777; called by mutect2, varscan2
- ITGA5 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53220562; called by mutect2, varscan2
- ITGAD | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 92/147 reads (63%) | SIFT tolerated (0.48); PolyPhen benign (0.093); catalogued as COSV66760060; called by muse, mutect2, varscan2
- ITGB2 | c.1237G>A p.G413R (on ENST00000302347; = p.G389R on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs372510204; ClinVar: uncertain significance; called by muse, varscan2
- ITGB8 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV56013816; called by muse, mutect2, varscan2
- ITPR1 | c.2270C>T p.S757L (on ENST00000354582; = p.S742L on NM_002222.7) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV57002271; called by mutect2, varscan2
- ITPRID1 | c.3067G>A p.A1023T | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs773210193, COSV100087442; called by muse, mutect2, varscan2
- IVL | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as rs776241645, COSV64217037; called by mutect2, varscan2
- IWS1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.006); catalogued as COSV54871621; called by muse, mutect2, varscan2
- KANK4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); catalogued as COSV62989197; called by muse, mutect2, varscan2
- KANSL1 | c.2888C>T p.P963L (on ENST00000574590 / NM_001193465.2; = p.P964L on NM_015443.4) | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV52247072; called by muse, mutect2, varscan2
- KATNAL2 | c.1598G>A p.R533K (on ENST00000356157 / NM_001353899.1; = p.R461K on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV55308076; called by muse, mutect2, varscan2
- KATNBL1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.637); catalogued as rs781035214, COSV56625466; called by mutect2, varscan2
- KCNA5 | c.853C>G p.P285A | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV52908466; called by muse, varscan2
- KCNA5 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.021); catalogued as rs764006390, COSV99364182; called by muse, mutect2, varscan2
- KCND1 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV54415855; called by muse, mutect2, varscan2
- KCNH1 | c.1798G>A p.V600M (on ENST00000271751 / NM_172362.3; = p.V573M on NM_002238.4) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV55100878; called by muse, mutect2, varscan2
- KCNH7 | c.2896G>A p.D966N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs370772173, COSV100147559; called by muse, mutect2, varscan2
- KCNH7 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as rs138091231; called by mutect2, varscan2
- KCNH8 | c.2177C>T p.S726F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as rs764123756, COSV60460701; called by mutect2, varscan2
- KCNH8 | c.3041C>T p.P1014L | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV60475772; called by muse, mutect2, varscan2
- KCNJ6 | c.979A>C p.T327P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.243); catalogued as COSV55722468; called by muse, varscan2
- KCNK15 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65720700; called by muse, varscan2
- KCNK5 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.327); catalogued as COSV63989366; called by muse, mutect2, varscan2
- KCNN3 | c.1604G>A p.G535E (on ENST00000618040 / NM_001204087.1; = p.G520E on NM_002249.6) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55226049; called by muse, mutect2, varscan2
- KCNS3 | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769974575, COSV58408809; called by muse, mutect2, varscan2
- KCNT2 | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs867616993, COSV54079273, COSV99038344; called by mutect2, varscan2
- KCNT2 | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99656604; called by muse, mutect2, varscan2
- KDM5B | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52512572; called by muse, mutect2, varscan2
- KERA | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.62); PolyPhen benign (0.048); catalogued as COSV57131734; called by muse, mutect2, varscan2
- KHDRBS2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV55489420; called by mutect2, varscan2
- KIAA0319L | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV57850299; called by muse, mutect2, varscan2
- KIAA1109 | c.9148C>T p.P3050S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52678781; called by muse, mutect2, varscan2
- KIAA1210 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.084); catalogued as COSV101274378; called by muse, mutect2, varscan2
- KIAA1217 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV56823260; called by mutect2, varscan2
- KIAA1522 | c.1085C>T p.S362F (on ENST00000373480 / NM_001198972.2; = p.S421F on NM_020888.3) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53862734; called by muse, mutect2, varscan2
- KIF17 | c.578G>A p.W193* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as COSV56122174; called by muse, mutect2, varscan2
- KIF21B | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250955515, COSV59763268; called by mutect2, varscan2
- KIF27 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 137/257 reads (53%) | catalogued as rs148451065; called by muse, mutect2, varscan2
- KIF5C | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs764718591, COSV68479597; called by mutect2, varscan2
- KLF11 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59941547; called by muse, mutect2, varscan2
- KLF7 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.099); catalogued as COSV58746433; called by muse, mutect2, varscan2
- KLHDC7B | c.1283G>A p.W428* (on ENST00000395676; = p.W1069* on NM_138433.5) | Nonsense Mutation (SNP) | VAF 82/213 reads (38%) | catalogued as COSV67465241; called by muse, varscan2
- KLHL4 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.196); catalogued as COSV64147578; called by muse, mutect2, varscan2
- KLHL4 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64147586; called by muse, mutect2, varscan2
- KLRF1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as COSV54382030; called by muse, mutect2, varscan2
- KMT2C | c.5005C>T p.P1669S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51498647; called by muse, mutect2, varscan2
- KMT2D | c.8686C>T p.P2896S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56424323; called by muse, mutect2, varscan2
- KPNA2 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 95/588 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV57858934; called by muse, mutect2, varscan2
- KRT2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs763294290, COSV59012564; called by muse, mutect2, varscan2
- KRT23 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV52928927; called by muse, mutect2, varscan2
- KRT25 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV56446533; called by muse, mutect2, varscan2
- KRT26 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56972359, COSV56973267; called by muse, mutect2, varscan2
- KRT32 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99863145; called by muse, mutect2, varscan2
- KRT32 | c.339G>T p.R113S | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV99863172; called by mutect2, varscan2
- KRT32 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs563544065, COSV56788057; called by muse, mutect2, varscan2
- KRT33B | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV52440090; called by mutect2, varscan2
- KRT82 | c.747G>C p.E249D | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57787176; called by muse, mutect2, varscan2
- KRTAP13-1 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs1408828240, COSV62664316; called by muse, mutect2, varscan2
- L3MBTL3 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62386485; called by mutect2, varscan2
- L3MBTL4 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV53139312; called by muse, mutect2, varscan2
- L3MBTL4 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53139324; called by mutect2, varscan2
- LAMA1 | c.7010C>T p.S2337L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67543992; called by mutect2, varscan2
- LAMA1 | c.3882G>A p.W1294* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | catalogued as COSV67534111; called by muse, mutect2, varscan2
- LAMA1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768160905, COSV67543996; called by mutect2, varscan2
- LAMA3 | c.8819G>A p.G2940D (on ENST00000313654 / NM_198129.4; = p.G1331D on NM_000227.6) | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.106); catalogued as rs758044833, COSV52542947; called by muse, mutect2, varscan2
- LAMA5 | c.7388G>A p.G2463E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53356628; called by muse, mutect2, varscan2
- LAMA5 | c.7387G>A p.G2463R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768563115, COSV99438523; called by mutect2, varscan2
- LAMB3 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as rs369131781; called by muse, varscan2
- LAMC1 | c.2603T>G p.F868C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51174481; called by muse, mutect2, varscan2
- LAMC3 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs994955035, COSV63095154; called by muse, mutect2, varscan2
- LAMC3 | c.4322C>T p.S1441F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV62654303; called by muse, mutect2, varscan2
- LAMP5 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV55717907; called by muse, mutect2, varscan2
- LATS1 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV53599370; called by muse, mutect2, varscan2
- LATS2 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66879521; called by muse, mutect2, varscan2
- LAX1 | c.1001G>A p.C334Y | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65850116; called by mutect2, varscan2
- LCE2C | c.79A>G p.K27E | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV64228703; called by muse, mutect2, varscan2
- LCOR | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53714647, COSV53717203; called by mutect2, varscan2
- LDB3 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53949002; called by muse, mutect2, varscan2
- LEMD1 | c.452G>A p.G151D (on ENST00000367151; = p.V104I on NM_001001552.5) | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV65672116; called by muse, mutect2, varscan2
- LGR5 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 104/363 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV57009204; called by muse, mutect2, varscan2
- LIG3 | c.1472C>G p.S491C | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52011082; called by muse, mutect2, varscan2
- LILRB2 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs199908779, COSV58748141; called by muse, mutect2, varscan2
- LILRB2 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as rs1417874960, COSV58746122; called by muse, mutect2, varscan2
- LILRB5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV60260875; called by muse, varscan2
- LIM2 | c.320C>T p.S107F (on ENST00000596399 / NM_001161748.2; = p.S149F on NM_030657.4) | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55742233; called by muse, varscan2
- LIN28B | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); catalogued as COSV61497516; called by mutect2, varscan2
- LIN7A | c.385A>T p.N129Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54027622; called by muse, mutect2, varscan2
- LIPK | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV101344964, COSV101344997; called by muse, mutect2, varscan2
- LONP2 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53526002; called by muse, mutect2, varscan2
- LONP2 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53526012; called by muse, mutect2, varscan2
- LONRF2 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 140/319 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66542290; called by muse, mutect2, varscan2
1,601 further variants in this file (761 protein-altering or splice-affecting, 784 silent, 56 other) are not listed here.
